Surgical pathology report (de-identified scan), TCGA case TCGA-DQ-5625, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site University Of Michigan, specimen TCGA-DQ-5625-01A (Primary Tumor).

[page 1 of 3]
TCGA-DQ-5625

HISTORY:

with history of biopsy confirmed squamous cell carcinoma of right tongue. ✓

GROSS:

1. "Soft tissue adjacent to laryngeal nerve, deep margin" Received in a small container is a 0.3 cm soft tissue bit.
Frozen section control. ()
2. "Proximal laryngeal nerve branch" Received in a small container is a 0.2 cm soft tissue bit.
Frozen section control. ()
3. "Lateral tongue" Received in a small container is a 4 cm strip of tissue.
Frozen section control. ()
4. "Ventral tongue" A 2.2 cm soft tissue strip.
Frozen section control. ()
5. "Posterior floor of mouth" Received in a small container is a 1 cm soft tissue strip.
Frozen section control. ()
6. "Deep hypoglossal" Received in a small container is a 0.4 cm muscle fragment.
Frozen section control. ()
7. "Frenulum" Received in a small container are two 0.7 cm soft tissue bits.
Frozen section control. ()
8. "Right neck level I" Received in a small container is a 5 x 4.5 x 1.0 cm yellow-tan soft tissue mass, submandibular gland and lymph node identified.
8A. Section of submandibular gland and four possible lymph nodes.
8B. Five possible lymph nodes. ()
9. "Right neck level II" Received in a small container is a 3 x 1.5 x 0.5 cm yellow-tan soft adipose tissue. Multiple lymph nodes identified.
9A. Three small lymph nodes and one big node, the bigger node is bisected and inked green.
9B. Two lymph nodes, both bisected; one inked green. ()
10. "Right neck, level III" Received in formalin in a small container is a 4.0 x 2.5 x 0.4 cm yellow-tan soft fibroadipose tissue. Lymph nodes identified.
10A. Four possible lymph nodes. ()
- 10B. One big lymph node, quadrisected. ()
11. "Right neck level 4" Received in formalin in a small container is a 4.0 x 2.0 x 0.8 cm yellow-tan soft fibroadipose tissue. Multiple lymph nodes identified and put into cassette 11A and 11B.
11A.&B. Six possible lymph nodes. ()
12. "Lateral tongue" Received in formalin in a small container is a 3.7 x 2.1 x 1.0 cm oriented right lateral tongue, 1.5 x 0.7 x 0.4 cm ulcer is noted in the center of the membranous site. The deep surface of superior aspect inked blue, the deep surface of inferior aspect inked green.
12A. The anterior margin.
12B. The posterior margin.
12C.-H. Serial section of the sample from anterior to posterior with sections containing ulcer in cassette C-G. ()
- Plea e note: ()

FROZEN SECTION REPORT

[page 2 of 3]
1.-7. Negative for carcinoma. [REDACTED]

[REDACTED] [REDACTED] have reviewed and interpreted the frozen section material at the time it was requested.

Permanent sections confirm frozen section reports.

[REDACTED] [REDACTED]

MICROSCOPIC:

SQUAMOUS LESIONS OF HEAD & NECK: RESECTION

Site: Right lateral tongue

Squamous carcinoma. Differentiation: Moderate.

Gross: Ulcerating Size 1.5 cm (largest dimension)

Invasion: Present If present: depth 0.5 cm.

Tumor border: Infiltrative

Perineural invasion: Absent

Vascular invasion: Absent

Bone/Cartilage invasion: N/A

Lymphocyte infiltration: Present If present: Moderate

Margins: Negative

SQUAMOUS LESIONS OF HEAD & NECK: LYMPH NODE DISSECTIONS

RIGHT

LEVEL

(or site)

#Positive

#Negative

Extracapsular
extension

I

0

6

-

II

0

5

-

III

0

3

-

IV

0

5

-

TOTAL

0

19

-

MICROSCOPIC DIAGNOSIS:

[page 3 of 3]
- 1-7. Margins, sites as specified above, biopsies: Negative for carcinoma.
8. Right neck, lymph nodes at level I, excision: Six lymph nodes, negative for carcinoma.
9. Right neck, lymph nodes at level II, excision: Five lymph nodes, negative for carcinoma.
10. Right neck, lymph nodes at level III, excision: Three lymph nodes, negative for carcinoma.
11. Right neck, lymph nodes at level IV, excision: Five lymph nodes, negative for carcinoma.
12. Right tongue, excision: Invasive, keratinizing squamous cell carcinoma (1.5 cm), deepest invasion 0.5 cm. No perineural or vascular invasion identified. Please see template for details.
- [REDACTED]
- [REDACTED]
- [REDACTED]
- [REDACTED]
- [REDACTED]
- [REDACTED]
- [REDACTED]
- [REDACTED] signature)
- [REDACTED]

Close

Source: NCI Genomic Data Commons file 2fafcf46-18e2-43ee-b963-674c5858e8f5 (TCGA-DQ-5625.A6074D57-4B7A-47E7-BF34-ED19F00E731C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).